Gene-level copy-number profile of specimen HCM-BROD-0873-C43-85B from HCMI case HCM-BROD-0873-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 66.8 years (24,401 days).
Specimen HCM-BROD-0873-C43-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 21329e19-56af-4a59-8f7a-91e83644814a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0873-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/06f5e1a0-eeb9-46d7-adf2-970dedc51b42

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 522; copy number 2: 6,940; copy number 3: 21,762; copy number 4: 18,643; copy number 5: 7,251; copy number 6: 2,532; copy number 7: 1,209; copy number 8: 22; copy number 9: 1; copy number 20: 3.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–4): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–21,996,013, 1 gene (within-gene range 0–4): AL449423.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,235 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–71,585, 9 genes, copy number 8: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5.
- chr3:119,468,963–119,818,485, 16 genes, copy number 7: POGLUT1, AC073352.1, TIMMDC1, CD80, AC073352.2, ADPRH, PLA1A, RPL10P7, POPDC2, COX17, AC023494.1, CFAP91, AC069444.2, AC069444.1, NR1I2, PHBP8.
- chr5:70,751,184–71,133,287, 11 genes, copy number 8–20: GUSBP16, AC139272.1, CDH12P1, SERF1A, SMN1, AC139834.1, NAIP, GTF2H2, OCLNP1, NAIPP4, CDH12P4.
- chr6:391,752–5,089,487, 104 genes, copy number 7 (broad region; genes not listed).
- chr6:29,353,749–58,438,364, 870 genes, copy number 7 (broad region; genes not listed).
- chr9:31,371,611–31,381,490, 1 gene, copy number 8: LINC01243.
- chr9:102,995,311–103,018,488, 1 gene, copy number 9: CYLC2.
- chr12:48,231,098–48,284,210, 1 gene, copy number 8: AC024257.1.
- chr14:22,190,158–22,482,959, 15 genes, copy number 7 (within-gene range 5–7): TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2.
- chr14:22,547,506–22,552,156, 1 gene, copy number 7: TRAC.
- chr20:87,250–7,371,692, 203 genes, copy number 7 (broad region; genes not listed).
- chr20:7,977,346–8,043,512, 2 genes, copy number 8: TMX4, AL021396.1.
- chr20:8,097,824–8,099,774, 1 gene, copy number 8: PHKBP1.

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
